Somatic mutation profile of tumor specimen TCGA-44-6777-01A (aliquot TCGA-44-6777-01A-11D-1855-08) from TCGA case TCGA-44-6777, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.5 years (31,234 days).
Specimen TCGA-44-6777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20c35f8f-5686-49a4-8c35-f25ac1cc53f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6777-10A (Blood Derived Normal), aliquot TCGA-44-6777-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b2cf63c-3857-4696-a6a3-dbe92f447ab0

The open-access MAF lists 387 somatic variants for this specimen: 294 protein-altering or splice-affecting, 83 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 83, Nonsense Mutation 16, Frame Shift Del 8, Splice Site 5, Intron 4, Frame Shift Ins 4, 5'Flank 3, In Frame Del 3, RNA 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFEMP2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs397514683, CM127922, COSV57260968; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55539024; called by muse, mutect2, varscan2
- ABCA8 | c.3196-1G>T p.X1066_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52207579; called by muse, mutect2, varscan2
- ACACB | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV100623339; called by muse, mutect2
- ACTL8 | c.827T>C p.I276T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV64862166; called by muse, mutect2, varscan2
- ADAMTS12 | c.3796C>A p.R1266S | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs756351049, COSV61271333, COSV61278184; called by muse, mutect2
- ADAMTS17 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs752421711, COSV51487712; called by mutect2, varscan2
- ADAMTS2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51083793; called by muse, mutect2, varscan2
- ADGRG2 | c.2206C>A p.L736I (on ENST00000379869 / NM_001079858.3; = p.L733I on NM_005756.4) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV61340331; called by muse, mutect2
- ADGRG4 | c.1370C>A p.A457E | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV54962357; called by muse, mutect2, varscan2
- AEBP1 | c.1179C>A p.H393Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV56259639; called by muse, mutect2, varscan2
- AK5 | c.509A>T p.K170M (on ENST00000354567 / NM_174858.3; = p.K144M on NM_012093.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58356538; called by muse, mutect2
- AKR1B10 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62056100; called by muse, varscan2
- ALG10 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1211309002, COSV56793504; called by muse, mutect2, varscan2
- ALK | c.1316G>T p.S439I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV66580811; called by muse, mutect2
- ALMS1 | c.7304C>G p.S2435C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52516293; called by muse, mutect2, varscan2
- AMER3 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV58467986, COSV58468561; called by muse, mutect2
- ANKEF1 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs756949223, COSV65693008, COSV65693026; called by muse, mutect2, varscan2
- ANKS1B | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61364103; called by muse, mutect2, varscan2
- ARHGAP36 | c.1340C>G p.A447G | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52264796; called by muse, mutect2, varscan2
- ASAP3 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60876489, COSV60878700; called by muse, mutect2
- ASB11 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs376376953, COSV100729166; called by muse, mutect2, varscan2
- ASXL3 | c.3107G>T p.R1036L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs776506817, COSV52473460; called by muse, mutect2, varscan2
- ATP2B4 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV58181314; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2398C>T p.L800F (on ENST00000343619 / NM_001378531.1; = p.L794F on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52876115; called by muse, mutect2, varscan2
- BCLAF1 | c.2647A>T p.S883C | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV50359202; called by muse, mutect2, varscan2
- BMP2 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV66578766; called by muse, mutect2
- BMP8A | c.1070T>C p.M357T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100090276; called by muse, mutect2
- BRINP3 | c.2087A>T p.Q696L | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV66533148; called by muse, mutect2, varscan2
- C3 | c.1519G>C p.V507L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV55577526; called by muse, mutect2, varscan2
- CAMSAP2 | c.4372A>G p.T1458A (on ENST00000236925 / NM_001297707.2; = p.T1447A on NM_203459.3) | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52674342; called by muse, mutect2, varscan2
- CAPN6 | c.800G>T p.R267I | Missense Mutation (SNP) | VAF 45/558 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV60696208; called by muse, mutect2
- CARMIL1 | c.3185G>T p.R1062L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV100277600, COSV61521132; called by muse, mutect2, varscan2
- CCDC83 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54703770; called by muse, mutect2, varscan2
- CCT2 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV54740930; called by muse, mutect2, varscan2
- CD86 | c.424G>A p.V142I (on ENST00000330540 / NM_175862.5; = p.V136I on NM_006889.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV52606235; called by muse, mutect2, varscan2
- CDH12 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66427479; called by muse, mutect2, varscan2
- CDH18 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56943696; called by muse, mutect2, varscan2
- CDH9 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV50351352; called by muse, mutect2, varscan2
- CDH9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs531958842, COSV50256671, COSV99162875; called by muse, mutect2
- CDHR3 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV58419604; called by muse, mutect2
- CDKL3 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99528190; called by muse, mutect2, varscan2
- CEP350 | c.2991G>T p.E997D | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.437); catalogued as COSV62606821; called by muse, mutect2, varscan2
- CFAP74 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54570824; called by muse, mutect2, varscan2
- CFH | c.2207G>T p.G736V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411119, COSV66414405; called by muse, mutect2, varscan2
- CHD8 | c.6634C>G p.P2212A (on ENST00000646647 / NM_001170629.2; = p.P1933A on NM_020920.4) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs747368212, COSV63037195; called by muse, mutect2
- CHD8 | c.5309C>T p.A1770V (on ENST00000646647 / NM_001170629.2; = p.A1491V on NM_020920.4) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV63037199; called by muse, mutect2, varscan2
- CHL1 | c.3532G>T p.D1178Y (on ENST00000397491 / NM_001253387.1; = p.D1194Y on NM_006614.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56599410; called by muse, mutect2, varscan2
- CHRDL1 | c.544C>T p.H182Y (on ENST00000372045; = p.H188Y on NM_145234.4) | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV54327097; called by muse, mutect2
- CIZ1 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV52973309; called by muse, mutect2, varscan2
- CNTN3 | c.2590G>T p.A864S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV55168331; called by muse, mutect2, varscan2
- COL6A3 | c.3603C>G p.I1201M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV55099798; called by muse, mutect2, varscan2
- COL7A1 | c.4520G>T p.G1507V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60399255; called by muse, mutect2
- CSMD3 | c.9149G>T p.G3050V (on ENST00000297405 / NM_001363185.1; = p.G2881V on NM_052900.3) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV52254661; called by muse, mutect2
- CSPP1 | c.2456A>C p.E819A (on ENST00000676605; = p.E778A on NM_024790.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.594); catalogued as COSV51588904; called by muse, mutect2, varscan2
- CTCFL | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs143392924, COSV54770842; called by muse, mutect2, varscan2
- CYP2B6 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs755100015, COSV57844954; called by muse, varscan2
- DBX2 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60338809; called by muse, mutect2
- DCAF4L2 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV60480617; called by muse, mutect2
- DCP1A | c.837_839del p.A280del | In Frame Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs782054270; called by pindel, varscan2
- DDX17 | c.1153A>T p.S385C | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV53254548; called by muse, mutect2, varscan2
- DGKB | c.2240T>G p.V747G | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV51804067; called by muse, mutect2, varscan2
- DMXL2 | c.8631-1G>C p.X2877_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV51841509, COSV51851316; called by muse, mutect2, varscan2
- DNAH9 | c.7925C>T p.A2642V | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs750150972, COSV52346119; called by muse, mutect2, varscan2
- DNAI3 | c.2425C>A p.H809N | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54004547; called by muse, mutect2, varscan2
- DPEP1 | c.1180T>G p.W394G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV55361230; called by muse, varscan2
- DSG3 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128193; called by muse, mutect2, varscan2
- DUSP11 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55594259, COSV55595414; called by muse, mutect2, varscan2
- EPHB1 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101214620; called by muse, mutect2, varscan2
- EPHB6 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs750830863, COSV67419987; called by muse, mutect2, varscan2
- F8 | c.6998T>A p.V2333E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV57705988; called by muse, mutect2
- F8 | c.4630C>A p.L1544I | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as COSV64276547; called by muse, mutect2
- FAM114A1 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV62673978; called by muse, mutect2, varscan2
- FAM189B | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV59170519; called by muse, mutect2
- FAT4 | c.5119G>T p.V1707L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.949); catalogued as COSV67894303; called by muse, mutect2
- FCGR2B | c.855+1G>T p.X285_splice | Splice Site (SNP) | VAF 23/117 reads (20%) | catalogued as COSV52682493; called by muse, mutect2, varscan2
- FCMR | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373086444; called by muse, mutect2
- FLG2 | c.4220G>C p.G1407A | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.623); catalogued as COSV101166068, COSV66171045; called by muse, mutect2
- FPGT-TNNI3K | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as COSV63047521; called by muse, mutect2, varscan2
- FSTL5 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV60213608; called by muse, mutect2, varscan2
- FYB1 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV60952082; called by muse, mutect2
- GABRG2 | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100729486, COSV62720379; called by muse, mutect2, varscan2
- GABRG3 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.354); catalogued as COSV61525687; called by muse, mutect2, varscan2
- GBP5 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193262844, COSV58593703; called by muse, mutect2
- GPN2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV64652436; called by muse, mutect2
- GPR101 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as COSV99981701; called by muse, mutect2
- GPR158 | c.3056T>A p.V1019E | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV66277068; called by muse, mutect2
- GPX6 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781203199, COSV62658506; called by muse, mutect2
- GRIN2A | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as rs555768104, COSV58047091, COSV58061733; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- GRIN2B | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.459); catalogued as COSV74206924; called by muse, mutect2, varscan2
- GSAP | c.1238T>C p.L413S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57531767; called by muse, mutect2, varscan2
- GUCY1A1 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); catalogued as rs967962212, COSV56654130; called by muse, mutect2
- H3C6 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.103); catalogued as COSV100839022; called by muse, mutect2
- H4C9 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV62890088; called by muse, mutect2
- HAPLN1 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57145295, COSV57150307; called by muse, mutect2, varscan2
- HCN4 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | catalogued as COSV56085310, COSV56085649; called by muse, mutect2, varscan2
- HERC4 | c.2330A>T p.E777V (on ENST00000395198 / NM_022079.3; = p.E769V on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53273420; called by muse, mutect2, varscan2
- HIVEP3 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV56019604; called by muse, mutect2, varscan2
- HRNR | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs552018177, COSV64254655; called by muse, mutect2, varscan2
- HYAL4 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV56139328, COSV99772498; called by muse, mutect2, varscan2
- IARS2 | c.1550G>C p.R517P | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56958400, COSV56962058; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1948A>T p.N650Y | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61169683; called by muse, mutect2, varscan2
- IQSEC3 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs1176668849, COSV100407673; called by mutect2, varscan2
- IRAK1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57655611; called by muse, mutect2
- IRX1 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV57361180; called by muse, mutect2, varscan2
- ITGA1 | c.132A>T p.E44D | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV50889635; called by muse, mutect2
- ITGA2 | c.2516C>A p.T839N | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56863753; called by muse, mutect2
- ITGA4 | c.425T>A p.V142E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV52002352; called by muse, mutect2, varscan2
- ITGA8 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65232651; called by muse, mutect2, varscan2
- ITGAX | c.1261G>T p.V421F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as rs1293621380, COSV51648839; called by muse, mutect2, varscan2
- ITM2B | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66035595; called by muse, mutect2, varscan2
- KALRN | c.4204G>A p.G1402S | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV53773916; called by muse, mutect2, varscan2
- KCNN2 | c.413C>T p.A138V (on ENST00000264773; = p.A350V on NM_021614.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53294893; called by muse, mutect2
- KHDRBS2 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55434726, COSV55467257, COSV55474548; called by muse, mutect2, varscan2
- KIAA1109 | c.10312G>T p.E3438* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV52684491; called by muse, mutect2, varscan2
- KIAA1210 | c.3731G>T p.S1244I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV68178709; called by muse, mutect2, varscan2
- KIFAP3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs1481730180, COSV63035549; called by muse, mutect2, varscan2
- KLHL6 | c.1302A>T p.R434S | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58068275; called by muse, mutect2, varscan2
- KMT2C | c.7366G>A p.A2456T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs527582568, COSV51436310, COSV51473012; called by muse, mutect2, varscan2
- KRT84 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV57772742; called by muse, mutect2, varscan2
- KRTAP19-7 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV58366380; called by muse, mutect2, varscan2
- LAG3 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.866); catalogued as COSV52568557; called by muse, mutect2, varscan2
- LANCL2 | c.1231C>G p.P411A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV54650974; called by muse, mutect2, varscan2
- LCE3B | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100167542, COSV59500621; called by muse, mutect2, varscan2
- LIG1 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 18/251 reads (7%) | catalogued as COSV54394101; called by muse, mutect2
- LILRA2 | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52194613; called by muse, mutect2, varscan2
- LIPI | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.913); catalogued as COSV60710218, COSV60714267; called by muse, mutect2, varscan2
- LMAN1 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV51828352; called by muse, mutect2, varscan2
- LPCAT1 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV52039731; called by muse, mutect2
- MAD2L1BP | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.328); catalogued as COSV64679400; called by muse, mutect2
- MAGEB18 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV57464648; called by muse, mutect2
- MAML1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52987603; called by muse, mutect2, varscan2
- MAP1A | c.6694C>A p.Q2232K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.062); catalogued as COSV55811133; called by muse, mutect2, varscan2
- MAP2 | c.3880G>T p.V1294L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52300456; called by muse, mutect2, varscan2
- MAP3K1 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV68125655; called by muse, mutect2
- MAP9 | c.1705G>C p.A569P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.748); catalogued as COSV60905633; called by muse, mutect2, varscan2
- MCAM | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50649124; called by muse, mutect2, varscan2
- MCM3 | c.148C>T p.R50W (on ENST00000229854 / NM_001366374.2; = p.A2V on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs754556530, COSV57718690; called by muse, mutect2, varscan2
- MCMBP | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV63510037; called by muse, mutect2, varscan2
- MED12 | c.5477C>T p.P1826L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as COSV61348936; called by muse, mutect2
- METTL21A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99777791; called by mutect2, varscan2
- MIEF2 | c.1226T>G p.I409S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100544154; called by muse, mutect2, varscan2
- MMP12 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.028); catalogued as COSV58260671; called by mutect2, varscan2
- MMP13 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV52824829; called by muse, mutect2, varscan2
- MOCOS | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54345558; called by muse, mutect2, varscan2
- MROH9 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV63012503; called by muse, mutect2, varscan2
- MS4A5 | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.324); catalogued as COSV55741723, COSV55742566; called by muse, mutect2
- MUC15 | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55553639, COSV55556054, COSV99846361; called by muse, mutect2, varscan2
- MUC16 | c.13795C>A p.L4599M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV67470526, COSV67480608; called by muse, mutect2, varscan2
- MUC3A | c.185A>C p.Q62P | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated, low confidence (0.1); catalogued as COSV100115502; called by muse, mutect2, varscan2
- MYH2 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV55443716; called by muse, mutect2, varscan2
- MYH7 | c.2664G>T p.Q888H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.832); catalogued as rs372875657, COSV62521706; called by muse, mutect2, varscan2
- MYO18A | c.1860G>C p.E620D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.371); catalogued as COSV62870525; called by muse, mutect2
- MYO1H | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs570225956, COSV100184061; called by muse, mutect2, varscan2
- NALCN | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51951855; called by muse, mutect2, varscan2
- NCAN | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53055001; called by muse, mutect2, varscan2
- NCKIPSD | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs542385660, COSV99584312; called by muse, mutect2, varscan2
- NEGR1 | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60859905; called by muse, mutect2, varscan2
- NEK10 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100412369; called by muse, mutect2
- NEXMIF | c.3800C>A p.P1267H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV50060436; called by muse, mutect2, varscan2
- NEXMIF | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); catalogued as COSV50060558; called by muse, mutect2, varscan2
- NFAT5 | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV63030283; called by muse, mutect2, varscan2
- NLRP7 | c.2237G>A p.R746H (on ENST00000340844 / NM_206828.3; = p.R718H on NM_139176.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as rs1370606415, COSV60178265; called by muse, mutect2
- NOTCH2 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 8/162 reads (5%) | catalogued as COSV56698833; called by muse, mutect2
- NUAK1 | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.201); catalogued as COSV54605954; called by muse, mutect2, varscan2
- NUP107 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1189646532, COSV57496477; called by muse, mutect2
- ODAM | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258018, COSV68573232; called by muse, mutect2, varscan2
- OR12D2 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV101011059, COSV65829259; called by muse, mutect2, varscan2
- OR2D3 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53494060; called by muse, mutect2, varscan2
- OR2G6 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1282494385, COSV100598341; called by muse, mutect2, varscan2
- OR2M3 | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 67/599 reads (11%) | catalogued as COSV71759195; called by muse, mutect2, varscan2
- OR2T4 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1326681302, COSV63544651; called by muse, mutect2, varscan2
- OR4L1 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV59850699; called by muse, mutect2, varscan2
- OR8U1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164153, COSV56414361; called by muse, mutect2, varscan2
- OTOGL | c.5965C>A p.Q1989K (on ENST00000547103; = p.Q1980K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs745406209, COSV100087985, COSV54019966; called by muse, mutect2, varscan2
- PAK3 | c.1571C>A p.S524Y (on ENST00000262836 / NM_001324328.2; = p.S509Y on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53278648, COSV99457298; called by muse, mutect2, varscan2
- PCBP3 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs201215749; called by muse, mutect2, varscan2
- PCDH11X | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015671; called by muse, mutect2, varscan2
- PCDHA1 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); catalogued as rs1462723431, COSV100974524; called by muse, mutect2
- PCDHB7 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.418); catalogued as COSV50756442, COSV50795007; called by muse, mutect2
- PHKG2 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60312294, COSV60313013; called by muse, mutect2, varscan2
- PITPNC1 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV55454918; called by muse, mutect2, varscan2
- PIWIL2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as COSV63252861; called by muse, mutect2
- PKD1L1 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV56972262; called by muse, mutect2, varscan2
- PKHD1 | c.4225G>T p.V1409L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.357); catalogued as COSV61887470; called by muse, mutect2, varscan2
- PKHD1L1 | c.11235T>G p.I3745M | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV65748394; called by muse, mutect2
- PLCXD3 | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV60613602; called by muse, mutect2, varscan2
- POLE | c.6137-2A>T p.X2046_splice | Splice Site (SNP) | VAF 15/163 reads (9%) | catalogued as COSV100268487, COSV99075334; called by muse, mutect2
- PPP2R5D | c.76A>T p.K26* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV57840952; called by muse, mutect2, varscan2
- PPRC1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV53387199; called by muse, mutect2, varscan2
- PRAMEF2 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53577547; called by muse, mutect2, varscan2
- PRKD1 | c.2195G>T p.R732L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59578015, COSV59585923; called by muse, mutect2
- PRLHR | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV99493000; called by muse, mutect2, varscan2
- PRUNE2 | c.7610C>A p.T2537K | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV65044556; called by muse, mutect2, varscan2
- PXDN | c.2763T>A p.H921Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as COSV53241275; called by muse, mutect2, varscan2
- PXDN | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | catalogued as COSV53232621, COSV53241287; called by muse, mutect2, varscan2
- RAB39A | c.408A>T p.Q136H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV100269330; called by muse, mutect2, varscan2
- RABEP2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs767378170, COSV62870302; called by muse, mutect2
- RABEPK | c.581A>G p.H194R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV52337183; called by muse, mutect2, varscan2
- RAD51C | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1060502588, CM1410422, COSV100507146; ClinVar: uncertain significance; called by muse, mutect2
- RAG1 | c.1544C>A p.P515Q | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55023867, COSV55026812; called by muse, mutect2, varscan2
- RANBP17 | c.44G>T p.C15F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66653981; called by muse, mutect2, varscan2
- RANBP2 | c.2523G>T p.W841C | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51705217; called by muse, mutect2, varscan2
- RBM19 | c.1991G>T p.S664I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV55695802; called by muse, mutect2
- RBM6 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV56485706; called by muse, mutect2
- REG1A | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52070649, COSV99286935; called by muse, mutect2, varscan2
- RLF | c.5638C>T p.H1880Y | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65652584; called by muse, mutect2
- RNF17 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55046353; called by muse, mutect2, varscan2
- RP2 | c.130G>T p.G44* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV54462691; called by muse, mutect2
- RPS6KA6 | c.2112G>T p.K704N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV53123663; called by muse, mutect2
- RUFY2 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV61191847, COSV61192415; called by muse, mutect2
- RYR2 | c.7239G>T p.K2413N | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63665928, COSV63700760; called by muse, mutect2, varscan2
- RYR3 | c.5132G>T p.R1711L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101214594, COSV66801666; called by muse, mutect2, varscan2
- SATB2 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53489382; called by muse, mutect2
- SCRN3 | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV55809046; called by muse, mutect2, varscan2
- SDE2 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV55252165; called by muse, mutect2, varscan2
- SEC14L5 | c.2066A>G p.H689R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.058); catalogued as rs754855917, COSV52040230; called by muse, mutect2, varscan2
- SERPINB9 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs202159163, COSV66233937; called by muse, mutect2, varscan2
- SEZ6L | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.444); catalogued as COSV50672665; called by muse, mutect2, varscan2
- SGMS2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1425626659, COSV62989488; called by muse, mutect2, varscan2
- SLC16A1 | c.1448C>G p.S483C | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV63709933; called by muse, mutect2
- SLITRK4 | c.2426G>C p.S809T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as COSV62025332; called by muse, mutect2
- SMAD2 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51022734; called by muse, mutect2, varscan2
- SMNDC1 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100852197; called by muse, mutect2, varscan2
- SNCAIP | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV54416399; called by muse, mutect2
- SPAG7 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV52778493; called by muse, mutect2, varscan2
- SPRED2 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62694648, COSV62695524; called by muse, mutect2, varscan2
- SRPK1 | c.1363T>G p.C455G | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV60414627; called by muse, mutect2
- SRPRA | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV55007952; called by muse, mutect2, varscan2
- SRPX2 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.581); catalogued as COSV65934134; called by muse, mutect2
- STAB1 | c.4077C>A p.H1359Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV58740444; called by muse, mutect2
- SUGP2 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766088837, COSV58262247; called by muse, mutect2
- SYNJ1 | c.3538G>C p.E1180Q | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.837); catalogued as COSV59152749; called by muse, mutect2
- TAF3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV60209205; called by muse, mutect2, varscan2
- TAS2R19 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV101115702; called by muse, mutect2, varscan2
- TAS2R3 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as COSV56092269; called by muse, mutect2, varscan2
- TAS2R39 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV71470950; called by muse, mutect2, varscan2
- TENM2 | c.4543G>T p.G1515W (on ENST00000518659 / NM_001122679.2; = p.G1276W on NM_001080428.3) | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69136542; called by muse, mutect2, varscan2
- TLR4 | c.973G>T p.D325Y (on ENST00000355622 / NM_138554.5; = p.D285Y on NM_003266.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62922415, COSV62922723; called by muse, mutect2, varscan2
- TMEM126B | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729065; called by muse, mutect2
- TMLHE | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57688466; called by muse, mutect2
- TNIK | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); catalogued as COSV52689589; called by muse, mutect2
- TNR | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs765569785, COSV54901502; called by muse, mutect2, varscan2
- TP63 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53214239, COSV53223531; called by muse, mutect2, varscan2
- TRAPPC9 | c.2399G>T p.C800F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV66905303; called by muse, mutect2, varscan2
- TSBP1 | c.947G>A p.G316E (on ENST00000617061; = p.G320R on NM_006781.5) | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.129); catalogued as COSV100898954; called by muse, mutect2, varscan2
- TSBP1 | c.946G>A p.G316R (on ENST00000617061; = p.Q319= on NM_006781.5) | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.184); catalogued as COSV100898955; called by muse, mutect2, varscan2
- TTN | c.32515G>A p.E10839K (on ENST00000591111; = p.E9912K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | PolyPhen probably damaging (0.987); catalogued as COSV60213243; called by muse, mutect2, varscan2
- TUB | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV59491934; called by muse, mutect2, varscan2
- UGT2B17 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100497317; called by mutect2, varscan2
- UNC79 | c.2123T>C p.F708S (on ENST00000393151 / NM_001346218.2; = p.F531S on NM_020818.5) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56400197; called by muse, mutect2
- UNC79 | c.5035C>G p.L1679V (on ENST00000393151 / NM_001346218.2; = p.L1502V on NM_020818.5) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV56400221; called by muse, mutect2
- UTS2B | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61280177; called by muse, mutect2, varscan2
- VN1R2 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100448210, COSV59038219; called by muse, mutect2, varscan2
- WDR36 | c.2440A>G p.K814E | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV72605374; called by muse, mutect2
- WNK3 | c.3901A>G p.R1301G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV63615131; called by muse, varscan2
- WNT7A | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53200879; called by muse, mutect2, varscan2
- ZC3H7A | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV63270656; called by muse, mutect2
- ZDBF2 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65628328; called by muse, mutect2
- ZMAT3 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100265404; called by muse, mutect2, varscan2
- ZNF121 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV57551346; called by muse, mutect2, varscan2
- ZNF233 | c.1915C>A p.Q639K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100492494; called by muse, mutect2, varscan2
- ZNF274 | c.1376G>A p.S459N (on ENST00000610905; = p.S354N on NM_016324.3) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58765683, COSV58766362; called by muse, mutect2
- ZNF492 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs763623690; called by mutect2, varscan2
- ZNF492 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101514069; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.502); catalogued as COSV53370099; called by muse, mutect2
- ZNF536 | c.1987G>T p.G663W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV62818405; called by muse, mutect2, varscan2
- ZNF536 | c.2526C>A p.F842L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV62829648; called by muse, mutect2, varscan2
- ZNF585A | c.1073A>T p.E358V (on ENST00000292841 / NM_001288800.2; = p.E303V on NM_152655.3) | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99493640; called by muse, mutect2, varscan2
- ZNF610 | c.320-2A>T p.X107_splice | Splice Site (SNP) | VAF 22/151 reads (15%) | catalogued as COSV100016847, COSV58345739; called by muse, mutect2, varscan2
- ZNF676 | c.1516G>T p.E506* (on ENST00000650058; = p.E474* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 31/143 reads (22%) | catalogued as COSV68092955, COSV68094067; called by muse, mutect2, varscan2
- ZNF683 | c.1300C>A p.R434S (on ENST00000403843; = p.R414S on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV62875131; called by muse, mutect2, varscan2
- ZNF804A | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56460891; called by muse, mutect2, varscan2
- ZNF831 | c.3560G>T p.C1187F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1236412427, COSV64043100; called by muse, mutect2, varscan2
- ZPBP | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50429685; called by muse, mutect2, varscan2
- ZSWIM2 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs1292451606, COSV54577428; called by muse, mutect2, varscan2
- CALCB | c.94_103del p.L32Afs*26 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | called by mutect2, pindel
- CSMD2 | c.7218del p.K2406Nfs*19 | Frame Shift Del (DEL) | VAF 22/209 reads (11%) | called by mutect2, pindel*
- DNAH10 | c.4887del p.F1630Sfs*24 (on ENST00000409039; = p.F1569Sfs*24 on NM_207437.3) | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | called by mutect2, pindel, varscan2
- ERCC6L | c.2562dup p.E855Rfs*12 | Frame Shift Ins (INS) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- FANCE | c.772del p.A258Qfs*38 | Frame Shift Del (DEL) | VAF 44/218 reads (20%) | called by mutect2, pindel, varscan2
- HADH | c.668dup p.V224Gfs*12 | Frame Shift Ins (INS) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- IFT46 | c.33_35del p.E12del | In Frame Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- IGKV2-24 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- LAMB1 | c.4755_4756dup p.T1586Kfs*11 | Frame Shift Ins (INS) | VAF 17/142 reads (12%) | called by mutect2, pindel, varscan2
- LAMB3 | c.1816del p.T606Pfs*20 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, varscan2
- LPAR1 | c.253del p.Y85Ifs*3 | Frame Shift Del (DEL) | VAF 19/124 reads (15%) | called by mutect2, pindel, varscan2
- LTBP1 | c.4924G>T p.G1642C (on ENST00000404816 / NM_206943.4; = p.G1316C on NM_000627.4) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR52B4 | c.439dup p.C147Lfs*28 | Frame Shift Ins (INS) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- SLC6A11 | c.450_464del p.L151_I155del | In Frame Del (DEL) | VAF 27/169 reads (16%) | called by mutect2, pindel
- STEAP1 | c.312_318del p.Q104Hfs*29 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | called by mutect2, pindel, varscan2
- TRIM15 | c.122_123del p.P41Rfs*102 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- ACRBP | c.1302C>T p.Y434= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs749150311, COSV57524800; called by muse, mutect2, varscan2
- ADAMTS10 | c.1560G>A p.L520= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV54357028; called by muse, mutect2, varscan2
- ADCY8 | c.2769C>A p.A923= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV53918292; called by muse, mutect2, varscan2
- AK5 | c.507G>A p.K169= (on ENST00000354567 / NM_174858.3; = p.K143= on NM_012093.4) | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV58356533; called by muse, mutect2
- ALAS2 | c.123G>T p.L41= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV58192251; called by muse, mutect2, varscan2
- ATP1A3 | c.258G>A p.P86= (on ENST00000545399 / NM_001256214.2; = p.P73= on NM_152296.5) | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs567997976, COSV57484745; called by muse, mutect2, varscan2
- C3AR1 | c.42C>A p.L14= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99369039; called by muse, mutect2
- C8orf74 | c.270C>A p.I90= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV58755023; called by muse, mutect2, varscan2
- CACNA2D4 | c.2142A>T p.P714= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV54955469; called by muse, mutect2, varscan2
- CD300LB | c.174C>T p.C58= | Silent (SNP) | VAF 36/207 reads (17%) | catalogued as rs1235012491, COSV58726063, COSV58726752; called by muse, mutect2, varscan2
- CDC20B | c.1383A>C p.A461= | Silent (SNP) | VAF 168/570 reads (29%) | catalogued as COSV57055049; called by muse, mutect2, varscan2
- CFAP47 | c.660G>T p.V220= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99935908; called by muse, mutect2, varscan2
- COL5A2 | c.1707A>T p.P569= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV66412081; called by muse, mutect2, varscan2
- CRACD | c.2433G>T p.V811= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV51727034; called by muse, mutect2, varscan2
- DDR1 | c.1380G>A p.T460= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as rs920330368, COSV61319934; called by muse, mutect2
- DDX46 | c.2334C>T p.F778= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV62800152; called by muse, mutect2
- DIP2B | c.2847A>G p.Q949= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV56588536; called by muse, mutect2, varscan2
- DNAH5 | c.11325G>T p.L3775= | Silent (SNP) | VAF 51/314 reads (16%) | catalogued as COSV54240801; called by muse, mutect2, varscan2
- EPB41L2 | c.63T>C p.D21= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV61357510; called by muse, mutect2
- F13B | c.319T>C p.L107= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV66374914; called by muse, mutect2, varscan2
- FAM133A | c.708G>A p.K236= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV59076754; called by muse, mutect2, varscan2
- FKBP10 | c.612C>T p.Y204= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1227407669, COSV58637889; called by muse, mutect2, varscan2
- GABRB2 | c.600A>T p.T200= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV50927955; called by muse, mutect2, varscan2
- GALNT10 | c.1143G>T p.P381= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs763250545, COSV51730697, COSV51733734; called by muse, mutect2, varscan2
- GIMAP1 | c.474C>T p.A158= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV56186956; called by muse, mutect2, varscan2
- GLIPR1L2 | c.567A>T p.I189= | Silent (SNP) | VAF 28/219 reads (13%) | catalogued as COSV57555162; called by muse, mutect2, varscan2
- GP5 | c.156C>G p.L52= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV55467457; called by muse, mutect2, varscan2
- GRID2 | c.2553G>A p.L851= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs753904458, COSV56236491; called by muse, mutect2, varscan2
- GRK7 | c.1503T>C p.D501= | Silent (SNP) | VAF 30/191 reads (16%) | catalogued as COSV53824298; called by muse, mutect2, varscan2
- H4C9 | c.192G>A p.E64= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs150377743, COSV62889809; called by muse, mutect2
- HDX | c.507A>T p.L169= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV52980580; called by muse, mutect2, varscan2
- IFI44 | c.1248T>A p.A416= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV66075243; called by muse, mutect2, varscan2
- IL21R | c.18C>A p.A6= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV61971672; called by muse, mutect2, varscan2
- INPP4B | c.1782G>A p.V594= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs749465710, COSV53736589; called by muse, mutect2, varscan2
- KANK4 | c.2961G>A p.A987= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs752783751, COSV58092958; called by muse, mutect2, varscan2
- KANSL1 | c.441A>T p.T147= | Silent (SNP) | VAF 54/606 reads (9%) | catalogued as COSV52271762; called by muse, mutect2
- KRT3 | c.183C>G p.G61= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as rs368081511, COSV58816485; called by muse, mutect2, varscan2
- LLGL2 | c.2637C>T p.P879= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1312962416, COSV51378586; called by muse, mutect2, varscan2
- LPXN | c.324A>C p.A108= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV67717720; called by muse, mutect2
- LRRC66 | c.1755A>T p.T585= | Silent (SNP) | VAF 13/215 reads (6%) | catalogued as COSV58635521; called by muse, mutect2
- MAB21L2 | c.57C>G p.R19= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100462466; called by muse, mutect2, varscan2
- MACF1 | c.3718C>T p.L1240= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV58389522; called by muse, mutect2, varscan2
- MAU2 | c.994C>T p.L332= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV53237048; called by muse, mutect2, varscan2
- MIOS | c.2316C>T p.V772= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as rs767260404, COSV60769838; called by muse, mutect2
- MTR | c.1167C>A p.L389= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100855586; called by muse, mutect2, varscan2
- MUC16 | c.8670G>A p.L2890= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV67480619; called by muse, mutect2, varscan2
- NEK8 | c.435C>T p.I145= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as rs773267212, COSV52047152; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOX1 | c.852G>A p.R284= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV54195822; called by muse, mutect2, varscan2
- OLFML2B | c.2211C>T p.D737= | Silent (SNP) | VAF 55/195 reads (28%) | catalogued as COSV54198653; called by muse, mutect2, varscan2
- OR10A6 | c.480A>G p.T160= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59166375; called by muse, mutect2, varscan2
- OR6F1 | c.672C>A p.T224= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV57468705; called by muse, mutect2, varscan2
- OXSM | c.747C>G p.S249= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV55002237; called by muse, mutect2, varscan2
- PCDHA1 | c.1173C>A p.P391= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV100974528; called by muse, mutect2
- PCDHAC1 | c.213C>A p.P71= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV53861425; called by muse, mutect2, varscan2
- PCDHGA11 | c.663C>T p.P221= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV53993515; called by muse, mutect2
- PCDHGC4 | c.1506A>G p.V502= | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as rs1416879364, COSV52759518; called by muse, mutect2, varscan2
- PIK3AP1 | c.738G>A p.L246= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs1291136909, COSV59534795; called by muse, mutect2
- PKP4 | c.1215G>T p.V405= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as COSV67678438; called by muse, mutect2, varscan2
- POF1B | c.1518G>T p.L506= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV53137678; called by muse, mutect2, varscan2
- POMC | c.726C>A p.T242= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99257020; called by mutect2, varscan2
- PPEF1 | c.825A>T p.T275= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV62996265; called by muse, mutect2, varscan2
- PPP4R4 | c.1257C>T p.C419= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as COSV100428222, COSV58556602; called by muse, mutect2
- PRAMEF14 | c.658C>T p.L220= | Silent (SNP) | VAF 100/727 reads (14%) | called by muse, mutect2, varscan2
- PTF1A | c.828A>G p.L276= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as COSV100919615; called by muse, mutect2, varscan2
- RAB39B | c.405C>T p.R135= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as COSV65624975; called by muse, mutect2
- RICTOR | c.1962C>T p.T654= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as COSV57127047; called by muse, mutect2
- S100A7 | c.153C>T p.G51= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV100906762; called by muse, mutect2, varscan2
- SAXO1 | c.171G>A p.R57= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV65871065; called by muse, mutect2, varscan2
- SDSL | c.561G>C p.L187= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100615290, COSV61884997; called by muse, mutect2, varscan2
- SHCBP1 | c.1959G>T p.G653= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV57649114, COSV57649326; called by muse, mutect2, varscan2
- SLC20A2 | c.780C>T p.L260= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV100646249; called by muse, mutect2
- SLC22A8 | c.288G>C p.L96= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as rs1421591002, COSV60326151; called by muse, mutect2, varscan2
- SLC25A42 | c.264C>T p.S88= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs755647825, COSV59381092; called by muse, mutect2, varscan2
- SPTBN5 | c.4599C>T p.L1533= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV58024976; called by muse, mutect2, varscan2
- TCHHL1 | c.1821G>C p.L607= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as rs1337323143, COSV64286701; called by muse, mutect2, varscan2
- TREM1 | c.135A>G p.L45= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV55149175; called by muse, mutect2
- UBC | c.849C>T p.T283= | Silent (SNP) | VAF 15/303 reads (5%) | catalogued as COSV60060511; called by muse, mutect2
- UGT1A6 | c.1407C>G p.G469= | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as COSV59391760, COSV59394258; called by muse, mutect2
- UGT2B17 | c.1239C>A p.A413= | Silent (SNP) | VAF 46/268 reads (17%) | catalogued as COSV100497319; called by muse, mutect2, varscan2
- UGT2B7 | c.537T>A p.T179= | Silent (SNP) | VAF 39/190 reads (21%) | catalogued as rs372601149; called by muse, mutect2, varscan2
- VIRMA | c.4605A>T p.P1535= | Silent (SNP) | VAF 44/224 reads (20%) | catalogued as COSV52588572; called by muse, mutect2, varscan2
- ZNF221 | c.1014C>T p.F338= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as COSV52110435; called by muse, mutect2
- ZNF559 | c.480A>T p.L160= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV57836601; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509182 C>G | 5'Flank (SNP) | VAF 20/333 reads (6%) | called by muse, mutect2
- AL133467.6 | chr14:95668222 G>T | 5'Flank (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- CHD8 | c.6772-271C>T | Intron (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100765387; called by muse, mutect2, varscan2
- DLG3 | c.1820-1341G>A | Intron (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99530135; called by muse, mutect2
- MIR519D | n.9T>A | RNA (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- MSRB3 | c.98-18207C>G | Intron (SNP) | VAF 12/132 reads (9%) | catalogued as COSV100378375; called by muse, mutect2, varscan2
- SLC5A9 | c.339+158T>C | Intron (SNP) | VAF 21/224 reads (9%) | catalogued as COSV99362040; called by muse, mutect2
- SSPOP | n.6695A>T | RNA (SNP) | VAF 4/35 reads (11%) | catalogued as COSV50488523; called by muse, mutect2
- TNS2 | chr12:53049154 G>C | 5'Flank (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100048737, COSV58582829; called by muse, mutect2, varscan2
- TREML2 | c.-16C>T | 5'UTR (SNP) | VAF 7/29 reads (24%) | catalogued as rs769905357, COSV101530140; called by muse, mutect2, varscan2
